TCGA case TCGA-10-0927 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/933dbfbd-4697-403e-bd73-c17cb300c94b

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Age at index: 65 years; Vital status: Dead; Days to death: 2,490 days (6.8 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 65.7 years (23,982 days); Year of diagnosis: 2000; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G2; Prior treatment: No.
   Pathology details: Residual tumor measurement: 1-10 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 9 days; Days to treatment end: 121 days; Number of cycles: 6; Treatment dose: 2,940 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 9 days; Days to treatment end: 121 days; Number of cycles: 6; Treatment dose: 1,800 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 1,017 days (2.8 years); Days to treatment end: 1,301 days (3.6 years); Number of cycles: 10; Treatment dose: 5,400 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Initial disease status: Progressive Disease; Days to treatment start: 1,336 days (3.7 years); Days to treatment end: 1,640 days (4.5 years); Treatment dose: 12,000 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Anastrozole; Initial disease status: Progressive Disease; Days to treatment start: 1,601 days (4.4 years); Days to treatment end: 1,686 days (4.6 years); Number of cycles: 10; Treatment dose: 60 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Progressive Disease; Days to treatment start: 1,686 days (4.6 years); Days to treatment end: 1,910 days (5.2 years); Number of cycles: 10; Treatment dose: 2,320 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 1,938 days (5.3 years); Days to treatment end: 2,302 days (6.3 years); Number of cycles: 10; Treatment dose: 845 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Progressive Disease; Days to treatment start: 2,330 days (6.4 years); Days to treatment end: 2,463 days (6.7 years); Number of cycles: 10; Treatment dose: 9,920 mg/m2; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 68.4 years (24,983 days); Days to diagnosis: 1,001 days (2.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 1,001 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 1,001 days (2.7 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 2,478 days (6.8 years); Disease response: With Tumor.
- Days to follow up: 2,490 days (6.8 years); Disease response: With Tumor.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-10-0927-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.1; Intermediate dimension: 0.7; Shortest dimension: 0.6.
  Slide TCGA-10-0927-01A-02-BS2: Section location: Bottom; Percent tumor cells: 60; Percent tumor nuclei: 75; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 30.
  Slide TCGA-10-0927-01A-01-BS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 5.
- Sample TCGA-10-0927-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Pharmaceutical therapy drug name: Arimidex; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Progression and Recurrence.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 3: Pharmaceutical therapy drug name: Doxil; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Progression and Recurrence.
- Drug treatment 5: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 7: Pharmaceutical therapy drug name: Taxol; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Progression and Recurrence.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,490 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 2,490 days; disease-free interval: event (new tumor event after initially disease-free), 1,001 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,001 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-10-0927-01A-02D-0399-01): tumor purity 0.82, ploidy 2.92, whole-genome doublings 1.
